Gene-level copy-number profile of tumor specimen TCGA-CG-4440-01A from TCGA case TCGA-CG-4440, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.9 years (25,171 days).
Specimen TCGA-CG-4440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.26532ab2-d511-4cdb-8169-552e18c5393b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4440-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bca8498b-6c2a-458d-8b94-e2b82917d416

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 117; copy number 1: 12; copy number 2: 5,868; copy number 3: 14,134; copy number 4: 31,326; copy number 5: 3,042; copy number 6: 2,404; copy number 7: 2,783; copy number 8: 40; copy number 9: 4; copy number 11: 33; copy number 39: 3; copy number 44: 14; copy number 49: 13; copy number 59: 1; copy number 74: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4440-01A-01D-1155-01): tumor purity 0.5, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 117 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–29,826,711, 117 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 88 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:104,502,700–104,503,266, 1 gene, copy number 49: AC091804.1.
- chr7:116,563,594–117,715,971, 38 genes, copy number 44–74 (within-gene range 7–74): COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1.
- chr7:119,178,177–120,227,213, 5 genes, copy number 9–59: AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2.
- chr8:127,072,694–127,482,139, 8 genes, copy number 44: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr8:127,663,280–127,742,951, 3 genes, copy number 39: AC108925.1, CASC11, MYC.
- chr20:52,192,159–54,269,542, 33 genes, copy number 11 (within-gene range 6–11): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
